Somatic mutation profile of tumor specimen C3L-00905-02 (aliquot CPT0063380009) from CPTAC case C3L-00905, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 65.0 years (23,742 days).
Specimen C3L-00905-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 645f018e-8d38-45ed-afbc-3ffece2dcd9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00905-31 (Blood Derived Normal), aliquot CPT0065250002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/843e0b25-9e7a-4664-b50d-4aa1b18c7715

The open-access MAF lists 74 somatic variants for this specimen: 51 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 12, Intron 7, Frame Shift Del 3, 5'UTR 2, In Frame Del 2, Nonsense Mutation 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 349/419 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CYP3A7 | c.801C>A p.H267Q | Missense Mutation (SNP) | VAF 129/363 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.171); catalogued as COSV60480830; called by muse, mutect2, varscan2
- DGKG | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 94/312 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs760143890; called by muse, mutect2, varscan2
- FAM184B | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0.065); catalogued as COSV53957258; called by muse, mutect2, varscan2
- GALNT7 | c.1529T>G p.F510C | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53934196; called by muse, mutect2, varscan2
- HCK | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs774332986, COSV52945788; called by muse, mutect2, varscan2
- KCNA6 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 137/510 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs781656226, COSV54974189, COSV54975172; called by muse, mutect2, varscan2
- LPL | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 90/349 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs779281032, COSV60933149; called by muse, mutect2, varscan2
- MRI1 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as rs1219236062; called by muse, mutect2, varscan2
- MYH4 | c.4732C>T p.R1578* | Nonsense Mutation (SNP) | VAF 49/140 reads (35%) | catalogued as rs779034071; called by muse, mutect2, varscan2
- NCOR2 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761242948; called by muse, mutect2, varscan2
- PCDHB3 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 220/616 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as rs781802448; called by muse, mutect2, varscan2
- PKD1 | c.5593C>T p.R1865W | Missense Mutation (SNP) | VAF 135/450 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs781643076; called by muse, mutect2, varscan2
- PNPLA7 | c.401C>G p.S134W | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52994048; called by muse, mutect2, varscan2
- RRAGD | c.1169C>A p.A390D | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.164); catalogued as COSV63270153; called by muse, mutect2, varscan2
- SPTA1 | c.3191A>T p.Y1064F | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63757333; called by muse, mutect2
- TAS2R39 | c.302T>G p.L101R | Missense Mutation (SNP) | VAF 75/317 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs1249363858; called by muse, mutect2, varscan2
- TCTN1 | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 156/423 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs946063938; called by muse, mutect2, varscan2
- TMEM178A | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.997); catalogued as rs766451293, COSV56141768; called by muse, mutect2, varscan2
- TTN | c.69301C>T p.R23101C (on ENST00000591111; = p.R15677C on NM_003319.4) | Missense Mutation (SNP) | VAF 66/137 reads (48%) | PolyPhen benign (0.003); catalogued as rs369489704; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWA3A | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs541691470; called by muse, mutect2, varscan2
- WNT6 | c.540C>A p.D180E | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52109627; called by muse, mutect2
- ABO | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 267/374 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ADNP | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 58/221 reads (26%) | called by muse, mutect2, varscan2
- AGO2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG7 | c.1696C>G p.R566G | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C19orf67 | c.514_523del p.L172Wfs*16 | Frame Shift Del (DEL) | VAF 14/151 reads (9%) | called by mutect2, pindel
- COL1A2 | c.3194A>G p.D1065G | Missense Mutation (SNP) | VAF 116/333 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CTNNA2 | c.1477G>T p.V493F | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DAO | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.012); called by muse, mutect2
- DYM | c.1449G>C p.Q483H | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GALNT3 | c.1260A>T p.K420N | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2
- IGHV3-20 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 19/395 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.109); called by muse, mutect2
- IQSEC2 | c.2248del p.D750Mfs*26 (on ENST00000642864 / NM_001111125.3; = p.D545Mfs*26 on NM_015075.2) | Frame Shift Del (DEL) | VAF 210/441 reads (48%) | called by mutect2, pindel, varscan2
- KIF5B | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LAMC2 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 108/367 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LPAR5 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUGGC | c.938_946del p.S313_I315del | In Frame Del (DEL) | VAF 27/110 reads (25%) | called by mutect2, pindel, varscan2
- PFKP | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASEL | c.1252G>T p.V418L | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.069); called by muse, mutect2
- SBK1 | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SERPINB10 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SPTA1 | c.860T>A p.L287H | Missense Mutation (SNP) | VAF 105/354 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TMSB10 | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 53/296 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TP53 | c.722_724del p.S241del | In Frame Del (DEL) | VAF 175/244 reads (72%) | called by mutect2, pindel, varscan2
- TRAV6 | c.305A>C p.K102T | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- WDR26 | c.1118G>T p.G373V (on ENST00000414423 / NM_001379403.1; = p.G273V on NM_025160.7) | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ZBTB7B | c.98_108del p.L33Hfs*8 (on ENST00000292176; = p.L67Hfs*8 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 115/220 reads (52%) | called by mutect2, pindel, varscan2
- ZNF630 | c.1515C>G p.H505Q | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- ZNF711 | c.1691G>T p.C564F | Missense Mutation (SNP) | VAF 87/330 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZSCAN4 | c.73T>C p.F25L | Missense Mutation (SNP) | VAF 98/132 reads (74%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BMERB1 | c.273G>A p.K91= | Silent (SNP) | VAF 50/148 reads (34%) | called by muse, mutect2, varscan2
- FAM131A | c.30C>G p.L10= | Silent (SNP) | VAF 50/196 reads (26%) | called by muse, mutect2, varscan2
- GBP5 | c.711C>T p.D237= | Silent (SNP) | VAF 183/361 reads (51%) | called by muse, mutect2, varscan2
- HMCN2 | c.747G>A p.G249= | Silent (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
- IK | c.1557C>T p.F519= | Silent (SNP) | VAF 45/155 reads (29%) | called by muse, mutect2, varscan2
- MAGEL2 | c.2025G>A p.A675= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1180033347; called by muse, mutect2, varscan2
- MED12L | c.747C>T p.H249= | Silent (SNP) | VAF 130/237 reads (55%) | catalogued as rs777825240; called by muse, mutect2, varscan2
- RANBP3L | c.1299C>T p.C433= | Silent (SNP) | VAF 59/150 reads (39%) | catalogued as rs769576272, COSV56955051; called by muse, mutect2, varscan2
- SHISA2 | c.528G>A p.S176= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as rs368288149; called by muse, mutect2, varscan2
- TMC5 | c.2463G>A p.Q821= (on ENST00000396229 / NM_001105248.1; = p.Q575= on NM_024780.5) | Silent (SNP) | VAF 30/71 reads (42%) | called by muse, varscan2
- ZFPL1 | c.402C>T p.L134= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs140383986; called by muse, mutect2, varscan2
- ZNF80 | c.354G>A p.S118= | Silent (SNP) | VAF 44/180 reads (24%) | catalogued as rs144823946; called by muse, mutect2, varscan2
- AC079174.2 | chr12:106254108 G>C | 3'Flank (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- ATIC | c.19+27C>G | Intron (SNP) | VAF 74/397 reads (19%) | called by muse, mutect2, varscan2
- EYS | c.-10C>G | 5'UTR (SNP) | VAF 58/235 reads (25%) | catalogued as rs1357375370; called by muse, mutect2, varscan2
- LAMB4 | c.2124+1102G>C | Intron (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- OR2U1P | n.196A>G | RNA (SNP) | VAF 30/144 reads (21%) | catalogued as rs749224742; called by muse, mutect2, varscan2
- PAX1 | c.287-206C>T | Intron (SNP) | VAF 59/259 reads (23%) | catalogued as COSV101270223; called by muse, mutect2, varscan2
- RNF212 | c.172-3002T>C | Intron (SNP) | VAF 113/319 reads (35%) | called by muse, mutect2, varscan2
- TBXAS1 | c.-58G>A | 5'UTR (SNP) | VAF 148/667 reads (22%) | catalogued as COSV99694717; called by muse, mutect2, varscan2
- TTC9C | c.239-2241T>G | Intron (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- WIPI1 | c.1293+1547G>A | Intron (SNP) | VAF 7/70 reads (10%) | catalogued as rs1200120170; called by muse, mutect2
- ZDHHC12 | c.101-12C>T | Intron (SNP) | VAF 57/84 reads (68%) | catalogued as rs200048079; called by muse, mutect2, varscan2
